Somatic mutation profile of tumor specimen TCGA-24-2290-01A (aliquot TCGA-24-2290-01A-01W-0799-08) from TCGA case TCGA-24-2290, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Specified parts of peritoneum; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.2 years (20,530 days).
Specimen TCGA-24-2290-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 733dee92-8f32-404b-9473-616e30ad780d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2290-10A (Blood Derived Normal), aliquot TCGA-24-2290-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb8625c0-8f2a-45a9-87ae-dd40403418d4

The open-access MAF lists 67 somatic variants for this specimen: 47 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 38, Silent 20, Frame Shift Del 5, In Frame Del 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 39/48 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057520006, COSV52662012, COSV52709979, COSV52761348, COSV53124293; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABLIM3 | c.1641C>A p.S547R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.575); catalogued as COSV58642678; called by muse, mutect2, varscan2
- ALG13 | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 53/70 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52639312; called by muse, mutect2, varscan2
- ATG9B | c.950T>A p.L317Q | Missense Mutation (SNP) | VAF 55/57 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65057816; called by muse, mutect2, varscan2
- BMP1 | c.2338A>T p.T780S | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60530159; called by muse, mutect2, varscan2
- CCDC136 | c.1060C>T p.R354W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775126730, COSV52797544; called by muse, mutect2, varscan2
- CDKN2C | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142420524; called by muse, mutect2, varscan2
- ECH1 | c.82A>G p.S28G | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs1209020628, COSV55489097; called by muse, mutect2
- EDC4 | c.2921G>A p.R974H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.613); catalogued as rs767777597, COSV59302577; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); catalogued as rs1444429131, COSV62567558; called by muse, mutect2, varscan2
- GPR149 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199967865, COSV67667010; called by muse, mutect2, varscan2
- GREB1 | c.3251A>T p.N1084I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV52185808, COSV52198191; called by muse, mutect2
- IL2RA | c.527G>A p.R176K | Missense Mutation (SNP) | VAF 153/431 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.012); catalogued as rs55841382, COSV56920530; called by muse, mutect2, varscan2
- KARS1 | c.1652T>A p.I551N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56691928; called by muse, mutect2, varscan2
- KDM5B | c.2221C>A p.L741I | Missense Mutation (SNP) | VAF 182/400 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52507231; called by muse, mutect2, varscan2
- LRRC41 | c.2296C>T p.H766Y | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV58439863; called by muse, mutect2, varscan2
- MED23 | c.4078G>A p.V1360M | Missense Mutation (SNP) | VAF 171/313 reads (55%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); catalogued as rs762236596, COSV51580932; called by muse, mutect2, varscan2
- MOGAT3 | c.1016C>A p.T339N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.494); catalogued as COSV56174113, COSV56177841; called by muse, mutect2, varscan2
- NLK | c.1407G>C p.K469N | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV101310994; called by muse, mutect2
- NLRP10 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.296); catalogued as COSV60779220; called by muse, mutect2, varscan2
- NRIP2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.039); catalogued as rs1170400589, COSV61701488; called by muse, mutect2, varscan2
- OR2W1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 114/262 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.386); catalogued as COSV65851432, COSV65851562, COSV65852021; called by muse, mutect2, varscan2
- PAPPA2 | c.4987_4996del p.V1663Nfs*17 | Frame Shift Del (DEL) | VAF 105/299 reads (35%) | catalogued as COSV62796379; called by mutect2, pindel, varscan2
- PCDHB12 | c.1508T>G p.L503R | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53396094; called by muse, mutect2, varscan2
- PEX5L | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 104/219 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV55844850; called by muse, mutect2, varscan2
- PODXL2 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV61065254; called by muse, mutect2, varscan2
- PTPRZ1 | c.1970C>A p.S657Y | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); catalogued as COSV101099885; called by muse, mutect2
- RBFA | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV51533625; called by muse, mutect2, varscan2
- RSPH3 | c.1168G>A p.E390K (on ENST00000252655; = p.E248K on NM_031924.8) | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs774313991, COSV51922323; called by muse, mutect2, varscan2
- SCN11A | c.1759A>G p.I587V | Missense Mutation (SNP) | VAF 267/662 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100181233; called by muse, mutect2, varscan2
- SETD2 | c.6528T>A p.Y2176* | Nonsense Mutation (SNP) | VAF 121/254 reads (48%) | catalogued as COSV57436612; called by muse, mutect2, varscan2
- SLC16A7 | c.812A>G p.Y271C | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768759461, COSV53894046; called by muse, mutect2, varscan2
- SORL1 | c.3799G>A p.D1267N | Missense Mutation (SNP) | VAF 627/714 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52753683; called by muse, mutect2, varscan2
- TRIM44 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 94/285 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV54982121; called by muse, mutect2, varscan2
- TTF1 | c.2241G>T p.K747N | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV57503698; called by muse, mutect2, varscan2
- ZBP1 | c.444G>C p.K148N | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.589); catalogued as rs1008927521, COSV59061500; called by muse, mutect2, varscan2
- ZFHX4 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50722964; called by muse, mutect2, varscan2
- ZNF582 | c.1160G>T p.R387I | Missense Mutation (SNP) | VAF 42/299 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56731310; called by muse, mutect2, varscan2
- EME1 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.129); called by mutect2, varscan2
- ETFDH | c.1484_1493del p.R495Qfs*27 | Frame Shift Del (DEL) | VAF 195/264 reads (74%) | called by mutect2, pindel, varscan2
- P4HA3 | c.1017_1052del p.K339_Y351delinsN | In Frame Del (DEL) | VAF 159/603 reads (26%) | called by mutect2, pindel
- PARP2 | c.1053_1100del p.Q352_C367del | In Frame Del (DEL) | VAF 81/357 reads (23%) | called by mutect2, pindel
- PCDHGC3 | c.143_151del p.G48_V50del | In Frame Del (DEL) | VAF 68/216 reads (31%) | called by mutect2, pindel, varscan2
- SUPT4H1 | c.60del p.L21Wfs*5 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | called by mutect2, pindel*, varscan2
- TARS1 | c.339_354del p.A114Lfs*4 | Frame Shift Del (DEL) | VAF 36/126 reads (29%) | called by mutect2, pindel
- TRIM27 | c.1024del p.Y342Tfs*34 | Frame Shift Del (DEL) | VAF 46/125 reads (37%) | called by mutect2, pindel, varscan2
- WASHC2C | c.3334G>C p.D1112H (on ENST00000336378; = p.D1091H on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/424 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- COL7A1 | c.2649G>A p.L883= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60394630; called by muse, mutect2
- CRHR2 | c.948G>A p.L316= | Silent (SNP) | VAF 202/514 reads (39%) | catalogued as rs376936813, COSV59265049; called by muse, mutect2, varscan2
- EFNB3 | c.429G>C p.G143= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as COSV56833374; called by muse, mutect2, varscan2
- FAM47A | c.2049G>A p.S683= | Silent (SNP) | VAF 191/367 reads (52%) | catalogued as COSV60496127; called by muse, mutect2, varscan2
- FAM71D | c.516C>T p.S172= | Silent (SNP) | VAF 19/104 reads (18%) | catalogued as COSV61295339; called by muse, mutect2, varscan2
- GRIK3 | c.354C>T p.T118= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as rs1450124115, COSV66138969; called by muse, mutect2, varscan2
- ITGB2 | c.1389G>A p.V463= (on ENST00000302347; = p.V439= on NM_000211.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as COSV56609739; called by muse, mutect2, varscan2
- LRRIQ3 | c.510T>C p.L170= | Silent (SNP) | VAF 13/122 reads (11%) | catalogued as COSV63043205; called by muse, mutect2, varscan2
- MTBP | c.2559T>C p.C853= | Silent (SNP) | VAF 70/101 reads (69%) | catalogued as COSV59962506; called by muse, mutect2, varscan2
- NEFH | c.1989T>G p.P663= | Silent (SNP) | VAF 36/125 reads (29%) | catalogued as CD991812, COSV60214745, COSV60220820; called by muse, varscan2
- NFRKB | c.3093C>T p.A1031= (on ENST00000446488 / NM_001143835.2; = p.A1056= on NM_006165.3) | Silent (SNP) | VAF 213/468 reads (46%) | catalogued as COSV58757710; called by muse, mutect2, varscan2
- OR10G8 | c.882G>T p.V294= | Silent (SNP) | VAF 76/658 reads (12%) | catalogued as COSV70908209, COSV70908463; called by muse, mutect2, varscan2
- PLOD1 | c.933C>T p.L311= | Silent (SNP) | VAF 14/16 reads (88%) | catalogued as COSV52143634; called by muse, mutect2, varscan2
- POLE | c.4182C>T p.V1394= | Silent (SNP) | VAF 109/119 reads (92%) | catalogued as rs1329622384, COSV57679287; called by muse, mutect2, varscan2
- RBM12 | c.1197A>G p.G399= | Silent (SNP) | VAF 68/169 reads (40%) | catalogued as COSV58291018; called by muse, mutect2, varscan2
- SMC5 | c.927A>T p.R309= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV63192635; called by muse, mutect2, varscan2
- SPOCK1 | c.1251C>A p.T417= | Silent (SNP) | VAF 562/1200 reads (47%) | catalogued as COSV99968504; called by mutect2, varscan2
- TAAR8 | c.117C>T p.S39= | Silent (SNP) | VAF 56/212 reads (26%) | catalogued as COSV51586153; called by muse, mutect2, varscan2
- TRIM44 | c.696C>T p.A232= | Silent (SNP) | VAF 93/286 reads (33%) | catalogued as rs757722204, COSV100194915; called by muse, mutect2, varscan2
- TTN | c.10068T>A p.T3356= (on ENST00000591111; = p.T3310= on NM_003319.4) | Silent (SNP) | VAF 74/166 reads (45%) | catalogued as COSV60015355; called by muse, mutect2, varscan2
